TCGA case TCGA-3B-A9HI — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34c39a6b-db6a-47e5-b0d4-5fa990ef7eb8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (4)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C49.1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Classification of tumor: primary; Age at diagnosis: 68.4 years (24,984 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 8; Tumor width measurement: 5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 8; Tumor width measurement: 5.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 70.1 years (25,590 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.5; Tumor length measurement: 2; Tumor width measurement: 1.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.17.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.5; Tumor length measurement: 2; Tumor width measurement: 1.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 23; Tumor width measurement: 3.17.
3. Metastasis of diagnosis 1 (Dedifferentiated liposarcoma), site: Lymph nodes of axilla or arm. Age at diagnosis: 70.6 years (25,775 days); Days to diagnosis: 791 days (2.2 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1; Tumor width measurement: 1.8.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4.3; Tumor width measurement: 2.9.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.9.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.8.
4. Metastasis of diagnosis 1 (Dedifferentiated liposarcoma), site: Lung, NOS. Age at diagnosis: 70.6 years (25,775 days); Days to diagnosis: 791 days (2.2 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.009.

Follow-up (5 entries)
- Day 606 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 606 days (1.7 years); Discontiguous lesion count: 23.
- Day 791 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 791 days (2.2 years).
- Day 791 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 791 days (2.2 years).
- Day 791 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of axilla or arm; Days to progression: 791 days (2.2 years).
- Days to follow up: 1,521 days (4.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 22.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-3B-A9HI-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Upper Extremity - Upper arm/elbow.
- Primary pathology: Margin status: Positive; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: Yes; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 8; Lesion radiologic width: 5; Lesion pathologic length: 8; Lesion pathologic depth: 5.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 850; Days from index date to pharmaceutical treatment ended: 959; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 850; Days from index date to pharmaceutical treatment ended: 959; Pharmaceutical therapy drug name: dacarbazine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 983; Days from index date to pharmaceutical treatment ended: 1262; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 983; Days from index date to pharmaceutical treatment ended: 1262; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1493; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: Yes.
- Radiation treatment: Days from index date to radiation therapy started: 59; Days from index date to radiation therapy ended: 114; Radiation therapy type: External; Radiation total dose: 8640; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 39; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,521 days; disease-specific survival: no event (censored), 1,521 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 606 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HI-01A-11D-A386-01): tumor purity 0.55, ploidy 3.33, whole-genome doublings 1.
